FM case AD5885 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts.
https://portal.gdc.cancer.gov/cases/0dffadf3-096d-4dd2-88c1-3a8c2e3bc9b6

Female, 31.0 years: Cholangiocarcinoma (ICD-O-3 8160/3) of the liver; primary biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
